TCGA case TCGA-G8-6914 — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3622cf29-600f-4410-84d4-a9afeb41c475

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 67.3 years (24,569 days); Year of diagnosis: 1996; AJCC staging edition: 4th; Ann Arbor clinical stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 5,980 days (16.4 years); Ann Arbor extranodal involvement: No; Sites of involvement: Lymph Node, Cervical.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP-21; Days to treatment start: 32 days; Days to treatment end: 165 days; Number of cycles: 6.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 77.3 years (28,238 days); Days to diagnosis: 3,669 days (10.0 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 3,669 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 5,616 days (15.4 years); Disease response: Tumor Free.
- Days to follow up: 5,980 days (16.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- CD19 (Flow Cytometry): Positive.
- CD20 (Flow Cytometry): Positive.
- CD22 (Flow Cytometry): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72.5 kg; Height: 172 cm; BMI: 24.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G8-6914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-G8-6914-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-G8-6914-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 95; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-G8-6914-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G8-6914-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: HIV status: Negative.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD22.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: Pet scan after treatment results: Not Done; Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 1: Stem cell transplantation: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Cytoxan; Stem cell transplantation: No.
- Drug treatment 3: Pharmaceutical therapy drug name: Adriamycin; Stem cell transplantation: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 5,980 days; disease-specific survival: no event (censored), 5,980 days; disease-free interval: event (new tumor event after initially disease-free), 3,669 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 3,669 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G8-6914-01A-11D-2209-01): tumor purity 0.55, ploidy 2.17, whole-genome doublings 0.
